Gene-level copy-number profile of tumor specimen TCGA-55-8089-01A from TCGA case TCGA-55-8089, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 56.3 years (20,576 days).
Specimen TCGA-55-8089-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.f17395cc-4dba-41b2-a123-aca5af1de185.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-8089-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bd07499e-f4f2-4354-b842-6b899410a0a6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 16,666; copy number 2: 39,723; copy number 3: 2,974; copy number 4: 226; copy number 8: 39; copy number 10: 5; copy number 13: 6; copy number 15: 33; copy number 18: 1; copy number 19: 16; copy number 23: 1; copy number 33: 45.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-8089-01A-11D-2237-01): tumor purity 0.33, ploidy 1.8, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 76 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:22,123,318–22,525,715, 76 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 146 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:8,938,787–8,939,369, 1 gene, copy number 15: AC009500.1.
- chr7:9,084,022–9,084,175, 1 gene, copy number 15: AC004852.1.
- chr7:22,419,444–23,105,703, 16 genes, copy number 19: STEAP1B, EEF1A1P6, AC002480.1, AC002480.2, IL6-AS1, IL6, MTCYBP42, AC073072.1, TOMM7, AC005682.2, SNHG26, SNORD93, AC005682.1, RPL12P10, FAM126A, KLHL7-DT.
- chr7:24,196,662–24,255,719, 1 gene, copy number 18 (within-gene range 2–18): AC004485.1.
- chr7:38,655,205–39,708,120, 15 genes, copy number 15: KRT8P20, FAM183BP, VPS41, POU6F2, POU6F2-AS2, SNORA20B, POU6F2-AS1, AC011290.1, YAE1, AC011290.2, AC004837.3, AC004837.1, AC004837.4, RALA, AC004837.2.
- chr7:45,940,449–47,948,466, 22 genes, copy number 10–15 (within-gene range 3–15): AC073115.2, AC073115.1, FTLP15, TTC4P1, ZNF619P1, AC023669.1, AC023669.2, AC004869.2, AC004869.1, HMGN1P19, AC011294.1, EPS15P1, AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1, AC087175.1, TNS3, LINC01447, C7orf65, PKD1L1.
- chr7:47,956,793–48,108,736, 5 genes, copy number 13: AC069282.1, HUS1, SUN3, C7orf57, UPP1.
- chr7:54,721,724–56,116,417, 45 genes, copy number 33: AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2.
- chr7:56,490,682–57,180,052, 39 genes, copy number 8: RBM22P3, AC092447.8, NMD3P2, AC092447.3, AC092447.5, VN1R25P, AC092447.2, AC092447.6, AC092447.1, AC092447.9, AC095038.5, TRIM60P16, AC095038.1, AC095038.4, AC095038.2, AC095038.3, CICP28, AC118758.2, AC118758.1, AC069152.1, MIR4283-1, TNRC18P3, SLC29A4P1, PHKG1P4, AC122133.1, ZNF479, AC099654.11, AC099654.2, AC099654.5, AC099654.8, MTATP6P8, MTCO3P10, AC099654.4, MTND4LP32, MTND4P4, MTND5P6, MTND6P29, MTCYBP29, GUSBP10.
- chr7:68,723,911–68,724,048, 1 gene, copy number 23: RNA5SP231.

Autosomal genes at a single copy (total copy number 1): 14,262. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
